FM case AD3948 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/6b89db27-dd60-451d-9af0-88daa016423c

Male, 45.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the eye. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
